Surgical pathology report (de-identified scan), TCGA case TCGA-32-1976, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-1976-01A (Primary Tumor).

NEUROPATHOLOGY REPORT

SPECIMEN SOURCE:

1. Left frontal tumor
2. Left frontal brain tumor
3. Left frontal lobe

GBM
CONTROL

CLINICAL DIAGNOSIS:

Brain tumor

TCGA-32-1976

GROSS DESCRIPTION:

1. Received fresh for frozen section labeled with the patient's name and "left frontal tumor" are multiple red-tan mucoid soft tissue fragments aggregating to 0.6 x 0.2 x 0.1 cm. A smear is performed with the remainder frozen on one chuck.

FROZEN SECTION DIAGNOSIS:

GLIOBLASTOMA.

The specimen is subsequently entirely resubmitted in one cassette for permanent sections.

2. Received in formalin labeled with the patient's name and "left frontal brain tumor" are multiple pink-tan hemorrhagic soft tissue fragments measuring in aggregate size 1.5 x 1.5 x 0.2 cm. The specimen is entirely submitted in one cassette.

3. Received in formalin labeled with the patient's name and "left frontal lobe" is a 4.2 x 3.1 x 1.1 cm portion of pink-tan soft tissue consistent with cortical brain. There are few foci of hemorrhage and possible tan discoloration. The specimen is serially sectioned perpendicular to the cortical surface, with representative sections (approximately 40%) submitted in three cassettes.

MICROSCOPIC DESCRIPTION:

- 1-3. Sections demonstrate a neoplasm with increased cellularity and pleomorphic nuclei. The mitotic rate is increased up to 15 mitoses per 10 high power fields. Necrosis is readily identified.

DIAGNOSIS:

(PROVISIONAL):

- 1-3. LEFT FRONTAL TUMOR, BIOPSY AND RESECTION:
GLIOBLASTOMA (WHO GRADE IV)

ADDENDUM NEUROPATHOLOGY REPORT

ADDENDUM DISCUSSION:

Approximately 25-50% of the tumor cells express MGMT.

ADDENDUM DIAGNOSIS:

- 1-3. LEFT FRONTAL TUMOR, BIOPSY AND RESECTION:
GLIOBLASTOMA (WHO GRADE IV)
- 25-50% EXPRESSION OF MGMT

Source: NCI Genomic Data Commons file 1d5c8fef-7ead-4e2b-a4e2-1d23c060431b (TCGA-32-1976.7FBD753B-801D-4A28-9673-F17B80C643AA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).